Somatic mutation profile of tumor specimen TCGA-E6-A2P8-01A (aliquot TCGA-E6-A2P8-01A-11D-A19Y-09) from TCGA case TCGA-E6-A2P8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 53.2 years (19,448 days).
Specimen TCGA-E6-A2P8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32f46d71-8c2a-47af-9d92-f865e6e67211.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E6-A2P8-10A (Blood Derived Normal), aliquot TCGA-E6-A2P8-10B-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/359beb98-62fb-4c2b-8170-af069f9efd43

The open-access MAF lists 689 somatic variants for this specimen: 525 protein-altering or splice-affecting, 152 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 342, Silent 152, Frame Shift Del 130, Frame Shift Ins 31, Splice Site 10, Nonsense Mutation 10, Intron 6, RNA 3, 3'Flank 1, Splice Region 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 26/113 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel
- COL3A1 | c.1662+1G>A p.X554_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as rs587779535, CS000451, CS1412514, CS1412515, COSV58589650; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCPS | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556401323, COSV55012888; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- GLDC | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs386833517, CM061029, COSV58675961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPS1 | c.972dup p.M325Hfs*128 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs281865082; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KCNH2 | c.453dup p.T152Hfs*180 | Frame Shift Ins (INS) | VAF 15/62 reads (24%) | catalogued as rs761863251; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MYC | c.131C>T p.A44V (on ENST00000377970; = p.A59V on NM_002467.6) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775522201, COSV52367462, COSV99422212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- ABCB6 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772815355, COSV54693434; called by muse, mutect2, varscan2
- ABCC3 | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99558824; called by muse, mutect2, varscan2
- ABRAXAS2 | c.184T>A p.C62S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100044863; called by muse, mutect2, varscan2
- AC004593.2 | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99764690; called by muse, mutect2
- ACKR2 | c.616T>C p.W206R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV99825388; called by muse, mutect2, varscan2
- ACOT9 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV100321223; called by muse, mutect2
- ACTC1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.491); catalogued as rs397517072, COSV51759700; ClinVar: uncertain significance; called by muse, mutect2
- ACTN3 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774833491, COSV101557813; called by muse, mutect2, varscan2
- ACVR1B | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57774982, COSV57781449; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2925del p.D976Tfs*37 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV99717810; called by mutect2, pindel, varscan2
- ADCY5 | c.1717G>T p.G573C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567408; called by muse, mutect2, varscan2
- ADD1 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs775330429, COSV53275200; called by muse, mutect2, varscan2
- ADGRG2 | c.366del p.F122Lfs*21 (on ENST00000379869 / NM_001079858.3; = p.F119Lfs*21 on NM_005756.4) | Frame Shift Del (DEL) | VAF 37/147 reads (25%) | catalogued as COSV61341022; called by mutect2, pindel, varscan2
- AGPAT4 | c.907dup p.R303Pfs*60 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | catalogued as rs750826126; called by mutect2, varscan2
- AHCY | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as rs745825646, COSV99464072; called by muse, mutect2, varscan2
- AKAP17A | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.247); catalogued as COSV100001963; called by muse, mutect2, varscan2
- ALG10B | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV100439819; called by muse, mutect2, varscan2
- ALKBH7 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99831693; called by muse, mutect2, varscan2
- ALOX12 | c.899T>A p.L300H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99277921; called by muse, mutect2
- ALPK3 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99360384; called by muse, mutect2, varscan2
- ANK1 | c.3844A>T p.S1282C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99224321; called by muse, mutect2, varscan2
- ANK3 | c.9640A>T p.K3214* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV55045541; called by muse, mutect2, varscan2
- ANKIB1 | c.1795A>G p.M599V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV99728565; called by muse, mutect2, varscan2
- ANKMY1 | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99801524; called by muse, mutect2
- ANKRD17 | c.3836A>G p.E1279G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100428677; called by muse, mutect2, varscan2
- ANKRD2 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100080743; called by muse, mutect2, varscan2
- ANKS6 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV100782232; called by muse, mutect2, varscan2
- ANLN | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs149506588; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs759218332; called by mutect2, varscan2
- AP2A1 | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV100756159; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 36/113 reads (32%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP10 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753952871, COSV100269993; called by muse, mutect2, varscan2
- ARHGAP30 | c.2501T>C p.V834A | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100920156; called by muse, mutect2
- ARHGAP31 | c.2236C>T p.H746Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99956707; called by muse, mutect2
- ARHGEF7 | c.1825G>A p.A609T (on ENST00000375741 / NM_001113511.2; = p.A431T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.043); catalogued as rs1260891170, COSV54549356; called by muse, mutect2, varscan2
- ARMC6 | c.866A>G p.N289S (on ENST00000392336; = p.N264S on NM_033415.4) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99522952; called by muse, mutect2, varscan2
- ARPC1A | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs755771767, COSV99500988; called by muse, mutect2, varscan2
- ARPP21 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99491280; called by muse, mutect2, varscan2
- ARSL | c.1597G>A p.V533M | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs376111412, COSV101140431; called by muse, mutect2, varscan2
- ASPH | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs773987662, COSV101063530; called by muse, mutect2, varscan2
- ASPHD2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs142083990; called by muse, mutect2, varscan2
- ATF4 | c.406dup p.Q136Pfs*44 | Frame Shift Ins (INS) | VAF 16/73 reads (22%) | catalogued as rs770192882; called by mutect2, varscan2
- ATP13A1 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294051277, COSV99179115; called by muse, mutect2
- ATP13A4 | c.1807T>C p.S603P | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs766017272, COSV99794148; called by muse, mutect2, varscan2
- ATRX | c.4169G>C p.S1390T | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100970222; called by muse, mutect2, varscan2
- ATRX | c.4168A>T p.S1390C | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100970223; called by muse, mutect2, varscan2
- B4GAT1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV100240151; called by muse, mutect2, varscan2
- BCL2L11 | c.287A>G p.Y96C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100427200; called by muse, mutect2, varscan2
- BEST3 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.101); catalogued as rs1326380921, COSV56995066; called by muse, mutect2, varscan2
- BIN1 | c.1541G>A p.R514H (on ENST00000316724 / NM_001320642.1; = p.R375H on NM_004305.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs766615886, COSV52123352; called by muse, mutect2, varscan2
- BRIP1 | c.2379+2T>C p.X793_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99369550; called by muse, mutect2, varscan2
- BSN | c.7603G>A p.A2535T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV99607571; called by muse, mutect2
- C11orf71 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.438); catalogued as rs979435910, COSV100348300; called by muse, mutect2, varscan2
- C1orf43 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV99670757; called by muse, mutect2, varscan2
- C3orf33 | c.294T>G p.I98M (on ENST00000340171 / NM_001308229.2; = p.I55M on NM_173657.2) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100420024; called by muse, mutect2, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- C6orf15 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV99456658; called by muse, mutect2, varscan2
- CA5A | c.264A>T p.E88D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99990465; called by muse, mutect2, varscan2
- CACNA1E | c.3158T>C p.L1053P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.731); catalogued as COSV100701439; called by muse, mutect2, varscan2
- CAMLG | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs1194849257, COSV99777706; called by muse, mutect2, varscan2
- CAMTA2 | c.1024A>G p.R342G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as rs779236594, COSV100772494; called by muse, mutect2, varscan2
- CAPN6 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1205899400, COSV60694273, COSV60695421; called by muse, mutect2, varscan2
- CAT | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1181088033; called by muse, mutect2
- CCDC127 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs563830939, COSV99722903; called by muse, mutect2, varscan2
- CCDC136 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs564211780, COSV52801795; called by muse, varscan2
- CCDC174 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs201187132; called by muse, mutect2, varscan2
- CCND1 | c.842T>A p.V281E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99919299; called by muse, varscan2
- CD40LG | c.614T>A p.L205* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as CM149767, COSV101033441; called by muse, mutect2, varscan2
- CDC42EP1 | c.197A>C p.N66T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV99312388; called by muse, mutect2, varscan2
- CDH22 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867452804, COSV64836773; called by muse, mutect2, varscan2
- CDKN2B | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs1167893458, COSV52805455; called by muse, mutect2
- CEBPE | c.216del p.G73Efs*48 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV99247497; called by mutect2, pindel, varscan2
- CELSR3 | c.8951A>G p.N2984S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.985); catalogued as COSV99372853; called by muse, mutect2, varscan2
- CFAP300 | c.710A>T p.N237I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs150444465; called by muse, mutect2, varscan2
- CFAP61 | c.2121del p.K707Nfs*11 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs1220155674; called by mutect2, pindel, varscan2
- CHD8 | c.7112dup p.N2371Kfs*2 (on ENST00000646647 / NM_001170629.2; = p.N2092Kfs*2 on NM_020920.4) | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | catalogued as rs751094013; called by mutect2, varscan2
- CHD8 | c.6620A>G p.E2207G (on ENST00000646647 / NM_001170629.2; = p.E1928G on NM_020920.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV100765257; called by muse, mutect2, varscan2
- CHERP | c.1362del p.W455Gfs*200 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as rs770045437; called by mutect2, varscan2
- CLIP2 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99791152; called by muse, mutect2, varscan2
- CLSTN1 | c.1997C>T p.A666V (on ENST00000377298 / NM_001009566.3; = p.A656V on NM_014944.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100790491; called by muse, mutect2, varscan2
- CLU | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.192); catalogued as COSV100324164; called by muse, mutect2, varscan2
- CMTM4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as COSV100411735; called by muse, mutect2, varscan2
- CNOT10 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1276064752, COSV100094136; called by muse, mutect2, varscan2
- CNOT11 | c.1056del p.D353Tfs*24 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs1184381827; called by mutect2, pindel, varscan2
- CNOT6 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.208); catalogued as COSV99993445; called by muse, mutect2, varscan2
- COL18A1 | c.4289del p.P1430Lfs*16 (on ENST00000359759 / NM_130444.3; = p.P1195Lfs*16 on NM_030582.4) | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs748210520; called by mutect2, pindel, varscan2
- COL6A1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as rs1226087945, COSV100720009; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.4409G>A p.R1470Q | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); catalogued as rs747756779, COSV100095363; called by muse, mutect2, varscan2
- COMMD4 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs140470549; called by muse, mutect2, varscan2
- CORO7 | c.2198C>A p.T733N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs760891363, COSV99227303; called by muse, mutect2, varscan2
- CPEB2 | c.3010C>T p.R1004C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99470078; called by muse, mutect2, varscan2
- CPXM1 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs776351140, COSV66045544; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRY1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs749506981, COSV50481097; called by muse, mutect2, varscan2
- CSMD1 | c.8707G>A p.D2903N (on ENST00000520002; = p.D2902N on NM_033225.6) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.914); catalogued as COSV59321665; called by muse, mutect2, varscan2
- CSRNP2 | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as COSV99950281; called by muse, mutect2
- CYB5A | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770734233, COSV55021610; called by muse, mutect2, varscan2
- CYFIP2 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as COSV59045421; called by muse, mutect2, varscan2
- CYP11A1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs781754675, COSV51430446; called by muse, mutect2, varscan2
- CYP3A4 | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV100315514; called by muse, mutect2, varscan2
- CYP4F11 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930685; called by muse, mutect2, varscan2
- DACH2 | c.1478G>T p.R493I | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs760287505, COSV100912692; called by muse, mutect2, varscan2
- DCAF5 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100432292; called by muse, mutect2, varscan2
- DDB1 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100074368; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX3X | c.169T>A p.S57T (on ENST00000399959; = p.S58T on NM_001356.5) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV101302361; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DENND11 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs771775238, COSV101530695; called by muse, mutect2, varscan2
- DENND4C | c.4040C>A p.P1347H (on ENST00000434457 / NM_001330640.2; = p.P1298H on NM_017925.7) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100727341; called by muse, mutect2, varscan2
- DISP3 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV99607664; called by muse, mutect2, varscan2
- DMBX1 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1463749642, COSV100760686; called by muse, mutect2
- DNAH7 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs371246623; called by muse, mutect2, varscan2
- DNMT3A | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99260205; called by muse, mutect2, varscan2
- DNMT3B | c.1359dup p.L454Afs*11 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs756395138; called by mutect2, varscan2
- DNTT | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100960467; called by muse, mutect2, varscan2
- DOCK10 | c.1122dup p.D375Rfs*6 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPP6 | c.949G>A p.A317T (on ENST00000377770 / NM_001364500.2; = p.A255T on NM_001936.5) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370802575, COSV59618705; called by muse, mutect2, varscan2
- DRICH1 | c.621+1G>A p.X207_splice | Splice Site (SNP) | VAF 30/100 reads (30%) | catalogued as rs370596219; called by muse, mutect2, varscan2
- DSCAML1 | c.3418G>A p.E1140K (on ENST00000321322; = p.E1080K on NM_020693.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58403335; called by muse, mutect2, varscan2
- DSN1 | c.862A>G p.M288V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV101040978; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs369293935; called by mutect2, varscan2
- EEF1AKNMT | c.2084C>T p.T695M (on ENST00000361735 / NM_015935.5; = p.T609M on NM_014955.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs575314244, COSV62283000; called by muse, mutect2, varscan2
- EFCAB6 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99412697; called by muse, mutect2
- EHF | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV99140882; called by muse, mutect2, varscan2
- EIF2AK4 | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.947); catalogued as COSV55465781; called by muse, mutect2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPRS1 | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as rs775379670, COSV100859329; called by muse, mutect2, varscan2
- EPS8L1 | c.1087C>G p.P363A (on ENST00000201647 / NM_133180.3; = p.P236A on NM_017729.3) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99135813; called by muse, mutect2, varscan2
- ERRFI1 | c.855del p.R286Efs*9 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs1557463619; called by mutect2, pindel, varscan2
- EXOC8 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as COSV99149519; called by muse, mutect2, varscan2
- EYS | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV100675850; called by muse, mutect2, varscan2
- FAM120C | c.1636C>T p.H546Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV100069687; called by muse, mutect2, varscan2
- FAM135A | c.3812T>C p.I1271T (on ENST00000370479 / NM_001351599.1; = p.I1058T on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99525400; called by muse, mutect2, varscan2
- FAM71C | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100175666; called by muse, mutect2, varscan2
- FAT3 | c.3640C>T p.R1214* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs1228580301, COSV53101062; called by muse, mutect2, varscan2
- FBLN2 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs1272556761, COSV55480844; called by muse, mutect2, varscan2
- FBN3 | c.4954G>A p.V1652I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99560181; called by muse, mutect2, varscan2
- FBP2 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs774922595, COSV100942085; called by muse, mutect2, varscan2
- FCER1A | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs755540332, COSV100929318, COSV63668462; called by muse, mutect2, varscan2
- FCRL6 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs772715372, COSV100220075, COSV58942056; called by muse, mutect2, varscan2
- FGR | c.1456T>C p.S486P | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as COSV100925779; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLG2 | c.1930C>A p.Q644K | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV66169381; called by muse, mutect2, varscan2
- FRYL | c.2734C>A p.P912T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.4); catalogued as COSV99976159; called by muse, mutect2, varscan2
- FUBP1 | c.736-2A>G p.X246_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | catalogued as COSV99628057; called by muse, mutect2, varscan2
- GATAD2A | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs750661945, COSV99389762; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GCAT | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as COSV50648966, COSV99959689; called by muse, mutect2, varscan2
- GEN1 | c.1259del p.K420Sfs*18 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | catalogued as rs1368422157; called by mutect2, pindel, varscan2
- GIGYF1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV99308952; called by muse, mutect2, varscan2
- GIMAP7 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as rs145339506, COSV57959733; called by muse, mutect2, varscan2
- GNB3 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs116400596; called by muse, mutect2, varscan2
- GOLIM4 | c.1891del p.R631Gfs*87 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs1210775698; called by mutect2, pindel, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs370114090; called by mutect2, varscan2
- GPBP1 | c.181A>G p.N61D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs761119314, COSV99302532; called by muse, mutect2, varscan2
- GPER1 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.905); catalogued as rs142494393; called by muse, mutect2, varscan2
- GPR22 | c.1192A>T p.N398Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99771567; called by muse, mutect2
- GPR89A | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100572370; called by muse, mutect2
- GRIK4 | c.1809del p.F604Sfs*27 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as COSV70801839; called by mutect2, pindel, varscan2
- GRK7 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.192); catalogued as COSV99379635; called by muse, mutect2, varscan2
- GSAP | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99990021, COSV99990339; called by muse, mutect2, varscan2
- GSX2 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482509; called by muse, mutect2
- GZMK | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50244614; called by muse, mutect2, varscan2
- H2BC7 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as rs563912649, COSV100587114; called by muse, mutect2, varscan2
- HCN2 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV99241399; called by muse, mutect2
- HEPHL1 | c.2903A>G p.H968R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100243623; called by muse, mutect2, varscan2
- HLA-DMA | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs765158083, COSV100877658; called by muse, mutect2, varscan2
- HOXC13 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99078875, COSV99673438; called by muse, mutect2, varscan2
- HSPB9 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs782568338, COSV56790807; called by muse, mutect2, varscan2
- IGDCC3 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.656); catalogued as rs756738425, COSV100030852; called by muse, mutect2, varscan2
- IGF2 | c.686del p.P229Qfs*27 (on ENST00000434045 / NM_001127598.3; = p.P173Qfs*27 on NM_000612.6) | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs755455183; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IGFBP2 | c.518del p.G173Efs*13 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV52079919, COSV52080557; called by mutect2, pindel, varscan2
- IGLV1-47 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs527799688; called by muse, mutect2, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV60863912; called by mutect2, pindel, varscan2
- IQCB1 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs370233738; called by muse, mutect2, varscan2
- IQCG | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54564621; called by muse, mutect2, varscan2
- IRAK1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100888953; called by muse, mutect2, varscan2
- IRS1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100524143; called by muse, mutect2, varscan2
- ITPR1 | c.7829C>T p.T2610M (on ENST00000354582; = p.T2555M on NM_002222.7) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268978821, COSV100230052; called by muse, mutect2
- ITPRIPL1 | c.1451G>A p.G484D (on ENST00000439118 / NM_001008949.3; = p.G492D on NM_178495.6) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV100742164; called by muse, mutect2, varscan2
- ITSN1 | c.2933G>T p.S978I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV66086872; called by muse, mutect2, varscan2
- JAK1 | c.475T>C p.F159L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100691239, COSV61092554; called by muse, mutect2
- JCAD | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs200411233, COSV64760632; called by muse, mutect2, varscan2
- KANSL1 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774841964, COSV52267096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs1206265094; called by mutect2, pindel, varscan2
- KCNE4 | c.397del p.E133Rfs*3 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs760505003; called by mutect2, pindel, varscan2
- KCNQ3 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs1162617343, COSV66475435; called by muse, mutect2, varscan2
- KCNT1 | c.2372C>T p.A791V (on ENST00000488444; = p.A810V on NM_020822.3) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV53703507, COSV99705179; called by muse, mutect2, varscan2
- KDM5C | c.4553G>T p.S1518I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100948871, COSV64767388; called by muse, mutect2, varscan2
- KIAA0895 | c.1067A>G p.K356R (on ENST00000297063 / NM_001100425.2; = p.K305R on NM_015314.3) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.402); catalogued as COSV99766564; called by muse, mutect2, varscan2
- KIF7 | c.2690G>A p.G897D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.151); catalogued as COSV101067330; called by muse, varscan2
- KLF8 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs771483872, COSV100808144; called by muse, mutect2, varscan2
- KLF8 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100808146; called by muse, mutect2, varscan2
- KLHL1 | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100917079; called by muse, mutect2, varscan2
- KLHL7 | c.954C>A p.D318E (on ENST00000339077 / NM_001031710.3; = p.D270E on NM_018846.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100177812; called by muse, mutect2, varscan2
- KMT2B | c.6413dup p.A2139Gfs*6 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs754806477; called by mutect2, pindel, varscan2
- KRT1 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99358545; called by muse, mutect2, varscan2
- KRTAP5-3 | c.227del p.G76Afs*190 | Frame Shift Del (DEL) | VAF 44/134 reads (33%) | catalogued as rs750587906; called by mutect2, pindel, varscan2
- LCT | c.4054G>A p.A1352T | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs775395005, COSV51554684, COSV99928819; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LENG8 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as rs143145059, COSV58728535; called by muse, mutect2, varscan2
- LIF | c.214del p.E72Sfs*15 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as COSV50776368; called by mutect2, varscan2
- LIN37 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs1364062334, COSV99137398; called by muse, mutect2, varscan2
- LIN7B | c.323T>C p.M108T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99674400; called by mutect2, varscan2
- LIPG | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as rs750197905, COSV99724308; called by muse, mutect2
- LIPG | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV99724312; called by muse, mutect2, varscan2
- LMO4 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as rs1189472665, COSV100983969; called by muse, mutect2, varscan2
- LMTK2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99806212; called by muse, mutect2, varscan2
- LRP2BP | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs111547365; called by muse, mutect2, varscan2
- LRRC4B | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975860; called by muse, mutect2, varscan2
- LSM14A | c.284A>G p.Q95R | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV70885237; called by muse, mutect2
- LTBP4 | c.3541C>T p.R1181W (on ENST00000308370 / NM_001042544.1; = p.R1144W on NM_003573.2) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs760834066, COSV99180812; called by muse, mutect2, varscan2
- LYG1 | c.102del p.G35Efs*12 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs1454146127; called by mutect2, pindel, varscan2
- MADD | c.3719A>G p.D1240G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100211144; called by muse, mutect2, varscan2
- MAP1A | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs754580033, COSV100288240; called by muse, varscan2
- MAP3K10 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs767775266, COSV99454089; called by muse, mutect2, varscan2
- MAP3K15 | c.3368C>T p.A1123V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs887751274, COSV100134273; called by muse, mutect2, varscan2
- MAP4K1 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs556360025, COSV101204127, COSV101204148; called by muse, mutect2, varscan2
- MAPK4 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV101245217; called by muse, varscan2
- MARK3 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV99357943; called by muse, mutect2, varscan2
- MCM3AP | c.5510C>T p.T1837I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99386573; called by muse, mutect2, varscan2
- MCM6 | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs1215512211, COSV51465722; called by muse, mutect2, varscan2
- MDH1 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as COSV99250876; called by muse, mutect2, varscan2
- MED1 | c.1670T>C p.M557T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV100327533; called by muse, mutect2, varscan2
- MEP1A | c.2085-2A>G p.X695_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100042452; called by muse, mutect2, varscan2
- MINK1 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs941322323, COSV100767045; called by muse, mutect2, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs546807245; called by mutect2, varscan2
- MLC1 | c.135del p.C46Afs*12 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as CD151534; called by mutect2, pindel, varscan2
- MOCS3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV54865714; called by muse, mutect2, varscan2
- MROH7 | c.3565-2A>G p.X1189_splice | Splice Site (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100988538; called by muse, mutect2, varscan2
- MRTFA | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs371095439, COSV62935111; called by muse, mutect2, varscan2
- MTA1 | c.1913dup p.S639Lfs*18 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | catalogued as rs1555433939; called by mutect2, varscan2
- MTHFR | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs750272108, COSV100453496; called by muse, mutect2, varscan2
- MXRA5 | c.6044C>T p.A2015V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.695); catalogued as COSV99475755; called by muse, mutect2, varscan2
- MXRA5 | c.1256C>T p.T419I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99476070; called by muse, mutect2, varscan2
- MYBPC2 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV100731657; called by mutect2, varscan2
- MYBPC3 | c.2642T>C p.V881A | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV99920009; called by muse, mutect2
- MYO18B | c.530del p.P177Lfs*55 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs748007891; called by mutect2, pindel, varscan2
- MYO1H | c.2726T>A p.F909Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.934); catalogued as COSV100183213; called by muse, mutect2, varscan2
- MYO7A | c.2815C>A p.H939N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV101289065; called by muse, mutect2, varscan2
- NARF | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV100559608; called by muse, mutect2, varscan2
- NAV2 | c.3173G>A p.G1058D (on ENST00000396087 / NM_001244963.2; = p.G1035D on NM_145117.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771443047, COSV100216267, COSV100216351; called by muse, mutect2, varscan2
- NBEAL1 | c.7496G>A p.G2499D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs1466493289, COSV101355412; called by muse, mutect2, varscan2
- NBEAL2 | c.7358C>T p.P2453L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs752268439, COSV52762238; called by muse, mutect2, varscan2
- NBR1 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769420426, COSV100357722; called by muse, mutect2, varscan2
- NDST1 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.781); catalogued as rs149727326; called by muse, mutect2, varscan2
- NEK8 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99261619; called by muse, mutect2, varscan2
- NETO2 | c.1313A>G p.H438R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100292367; called by muse, mutect2, varscan2
- NFRKB | c.3331G>A p.A1111T (on ENST00000446488 / NM_001143835.2; = p.A1136T on NM_006165.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.013); catalogued as rs770425865, COSV100451813; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NKG7 | c.260dup p.G88Rfs*76 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | catalogued as rs765087839; called by mutect2, pindel, varscan2
- NOTCH1 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.578); catalogued as COSV99486068; called by muse, mutect2, varscan2
- NPR2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100709348; called by muse, mutect2, varscan2
- NRP1 | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99587951; called by muse, mutect2, varscan2
- NUTM1 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs150578599; called by muse, varscan2
- OBSCN | c.16174G>A p.V5392M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs915825284, COSV99474634; called by muse, mutect2, varscan2
- OGDHL | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs375590345; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs1254479213; called by mutect2, pindel
- OR7C2 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.433); catalogued as COSV99934437; called by muse, mutect2, varscan2
- OSBPL7 | c.1356del p.C453Vfs*25 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs755751251; called by mutect2, varscan2
- PAGR1 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100232621; called by muse, mutect2, varscan2
- PAQR9 | c.1057A>G p.M353V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100503712; called by muse, mutect2, varscan2
- PARN | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV100420732; called by muse, mutect2, varscan2
- PARP3 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232231; called by muse, mutect2, varscan2
- PCDHB16 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV53357480, COSV99501022, COSV99501393; called by muse, varscan2
- PCDHGA1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.01); catalogued as rs776076044, COSV65294924, COSV65295117, COSV65297635; called by muse, varscan2
- PCDHGA1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs754685144, COSV65297868; called by muse, varscan2
- PCDHGA7 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as rs182497799, COSV53892197; called by muse, mutect2, varscan2
- PCNX3 | c.5099C>T p.A1700V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1228844195, COSV100856091; called by muse, mutect2
- PDE4D | c.550C>A p.H184N (on ENST00000340635 / NM_001104631.2; = p.H48N on NM_006203.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100505387, COSV58963600; called by muse, mutect2, varscan2
- PER2 | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99611521; called by muse, mutect2, varscan2
- PHACTR1 | c.1567A>G p.S523G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100275917; called by muse, mutect2, varscan2
- PHRF1 | c.2045T>C p.I682T (on ENST00000264555 / NM_001286581.2; = p.I681T on NM_020901.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1274217399, COSV99199633; called by muse, mutect2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs756552559; called by mutect2, varscan2
- PIGU | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99466013; called by muse, mutect2, varscan2
- PIK3CA | c.3197C>T p.A1066V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.038); catalogued as rs1253171657, COSV55892714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PISD | c.662C>T p.P221L (on ENST00000439502 / NM_001326412.1; = p.P187L on NM_014338.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs754079183, COSV99837196; called by muse, mutect2, varscan2
- PITPNM2 | c.2567A>G p.Q856R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.245); catalogued as rs1345654757, COSV99758445; called by muse, mutect2, varscan2
- PKN3 | c.2444A>G p.Q815R | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV99403369; called by muse, varscan2
- PKP3 | c.2270G>T p.S757I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100229853; called by muse, mutect2, varscan2
- PLCG1 | c.310T>A p.S104T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99718609; called by muse, mutect2, varscan2
- PLCXD2 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101210006; called by muse, mutect2, varscan2
- PLEKHF1 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71410524; called by muse, mutect2, varscan2
- PLPP2 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV54120014, COSV99514511; called by muse, mutect2
- PLPPR4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100927042; called by muse, mutect2, varscan2
- PLXNB2 | c.5224G>A p.A1742T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100833893; called by muse, mutect2, varscan2
- POC1B | c.542A>C p.N181T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.033); catalogued as COSV100544084, COSV57969886; called by muse, mutect2, varscan2
- POLG2 | c.128A>C p.H43P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV99857672; called by muse, mutect2, varscan2
- PPAT | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs554702793, COSV99947118; called by muse, mutect2, varscan2
- PPFIA1 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV99557008; called by muse, mutect2, varscan2
- PPHLN1 | c.35T>G p.I12S | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99871548; called by muse, mutect2
- PRDM12 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767397937, CM156917, COSV53390635; called by muse, mutect2
- PRDM2 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs138484684; called by muse, varscan2
- PRM2 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 11/72 reads (15%) | PolyPhen probably damaging (0.929); catalogued as COSV99617557; called by muse, mutect2, varscan2
- PROKR2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99449960; called by muse, mutect2, varscan2
- PSMA2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1250056473, COSV99785716; called by muse, mutect2, varscan2
- PSMD13 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100728752; called by muse, mutect2, varscan2
- PUM2 | c.1679del p.G560Vfs*4 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as COSV57578403; called by mutect2, pindel, varscan2
- RARS1 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs200758381, COSV99199056; called by muse, mutect2, varscan2
- RASAL1 | c.2138T>C p.L713P | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV99921496; called by muse, mutect2
- RASAL2 | c.1420A>G p.S474G | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100862468; called by muse, mutect2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM46 | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV99907936; called by muse, mutect2, varscan2
- RBMS3 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV99819894; called by muse, mutect2, varscan2
- RBP3 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.692); catalogued as rs576373730; called by muse, mutect2, varscan2
- RGL4 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV99318655; called by muse, mutect2, varscan2
- RGS12 | c.2805G>T p.Q935H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100122651; called by muse, mutect2
- RIF1 | c.6826-1G>T p.X2276_splice | Splice Site (SNP) | VAF 32/80 reads (40%) | catalogued as COSV54619592, COSV99690226; called by muse, mutect2, varscan2
- RIPK3 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.142); catalogued as rs1164139450, COSV99353012; called by muse, mutect2, varscan2
- RNF10 | c.1937A>C p.N646T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs554370538, COSV100378509, COSV58045937; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 38/83 reads (46%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RSPH10B | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100521228; called by muse, mutect2
- RTEL1 | c.3565C>T p.P1189S | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV99422803; called by muse, mutect2, varscan2
- RTL9 | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV101511647; called by muse, mutect2, varscan2
- RUSC1 | c.1754G>A p.R585H (on ENST00000368352 / NM_001105203.2; = p.R116H on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99429546; called by muse, mutect2
- SAMD9L | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100560427, COSV59082615; called by muse, mutect2, varscan2
- SCN3A | c.4820C>T p.A1607V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV99326025; called by muse, mutect2, varscan2
- SCNN1B | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV100225468; called by muse, mutect2
- SCNN1D | c.539del p.R180Pfs*17 (on ENST00000338555; = p.R344Pfs*17 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs1326165103, COSV57640659; called by mutect2, pindel, varscan2
- SEC23A | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351692320, COSV56979427; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEL1L2 | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV99532757; called by muse, mutect2, varscan2
- SEMA4F | c.1580A>T p.D527V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335801; called by muse, mutect2, varscan2
- SERPINA7 | c.592A>T p.M198L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV100568230; called by muse, mutect2, varscan2
- SERPINB1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV101058373; called by muse, mutect2, varscan2
- SETD2 | c.4953del p.F1651Lfs*12 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs759274882; called by mutect2, pindel, varscan2
- SGCA | c.791del p.P264Qfs*57 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | catalogued as COSV56248718; called by mutect2, pindel, varscan2
- SGSM2 | c.2416C>T p.R806C (on ENST00000426855 / NM_001098509.2; = p.R851C on NM_014853.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769208344, COSV52158324; called by muse, varscan2
- SHROOM2 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs755337260, COSV101098266; called by muse, mutect2, varscan2
- SHTN1 | c.1607del p.P536Qfs*45 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV53382008; called by mutect2, pindel, varscan2
- SIPA1L1 | c.3784C>T p.R1262W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775161795, COSV62168887; called by muse, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC23A3 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99840921; called by muse, mutect2, varscan2
- SLC25A4 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1011931645, COSV99861190; called by muse, mutect2, varscan2
- SLC25A42 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as rs773221554, COSV100588034; called by muse, mutect2, varscan2
- SLC6A11 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99594174; called by muse, mutect2, varscan2
- SLC6A9 | c.506T>C p.L169P (on ENST00000360584 / NM_201649.4; = p.L115P on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100746085; called by muse, mutect2, varscan2
- SLFNL1 | c.1048G>T p.G350W | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145050859, COSV100262825; called by muse, mutect2, varscan2
- SLK | c.2602A>C p.M868L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100211556; called by muse, varscan2
- SMG8 | c.2909del p.P970Lfs*7 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as COSV56284374; called by mutect2, pindel, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs768873484; called by mutect2, varscan2
- SOGA3 | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV64106669, COSV64109039; called by muse, mutect2, varscan2
- SOS1 | c.1153A>G p.S385G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV101216660; called by muse, mutect2
- SOS2 | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53569977, COSV99365554; called by muse, mutect2
- SP7 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199737097; called by muse, mutect2, varscan2
- SPAG1 | c.2089C>T p.R697* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as rs1434601711, CM139423, COSV99308538; called by muse, mutect2, varscan2
- SPAG17 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60457999; called by muse, mutect2, varscan2
- SPG11 | c.1193T>G p.V398G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99968194; called by muse, mutect2
- SRCAP | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760183638, COSV99349532; called by muse, mutect2, varscan2
- SRRM2 | c.7994C>A p.P2665H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99241293; called by muse, mutect2, varscan2
- SSX5 | c.229G>A p.A77T (on ENST00000347757 / NM_175723.1; = p.A118T on NM_021015.4) | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs200600341, COSV61255302, COSV61255941; called by muse, mutect2, varscan2
- STK32C | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV100062002; called by muse, mutect2, varscan2
- STRBP | c.1054T>C p.S352P | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100724108; called by muse, mutect2
- SULT1A1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1228005503, COSV100131629; called by muse, mutect2
- SUN1 | c.854C>T p.A285V (on ENST00000405266 / NM_001367651.1; = p.A248V on NM_001130965.3 and 17 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1393440678, COSV61779162; called by muse, mutect2, varscan2
- SYCP1 | c.1884del p.G629Vfs*8 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs762984894, COSV65697419; called by mutect2, varscan2
- SYN1 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1329415218, COSV99927213; called by muse, mutect2
- SYTL5 | c.25A>G p.N9D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.054); catalogued as COSV99936950; called by muse, mutect2, varscan2
- TAS1R1 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.023); catalogued as COSV100062771; called by muse, mutect2, varscan2
- TBC1D9B | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100783442; called by muse, mutect2, varscan2
- TBK1 | c.1382del p.K461Rfs*5 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs1178717934; called by mutect2, pindel, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs751224053; called by mutect2, pindel, varscan2
- TCIRG1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV55836442, COSV99693178; called by muse, mutect2
- TFDP1 | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100945750; called by muse, mutect2, varscan2
- TG | c.6173A>G p.Y2058C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV99599535; called by muse, mutect2, varscan2
- TGFBI | c.1502del p.P501Qfs*9 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs771515402; called by mutect2, pindel, varscan2
- THBS4 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV100644213; called by muse, mutect2, varscan2
- THEMIS2 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.435); catalogued as COSV100197928; called by muse, mutect2
- TLCD3A | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100021243; called by muse, mutect2
- TLE6 | c.1051A>G p.T351A (on ENST00000246112 / NM_001143986.2; = p.T228A on NM_024760.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as COSV99857977; called by muse, mutect2, varscan2
- TMEM131 | c.2444del p.N815Ifs*2 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs1559368991; called by mutect2, pindel, varscan2
- TMEM132D | c.618dup p.T207Hfs*29 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs747811524; called by mutect2, varscan2
- TMEM161B | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99680294; called by muse, mutect2, varscan2
- TMEM204 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs778002297, COSV99559770; called by muse, mutect2, varscan2
- TMEM254 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.119); catalogued as COSV100953536; called by muse, mutect2, varscan2
- TMEM62 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99543373; called by muse, mutect2, varscan2
- TNIP1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100161173; called by muse, mutect2, varscan2
- TNXB | c.10409del p.G3470Afs*51 (on ENST00000647633; = p.G3223Afs*51 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | catalogued as rs773500008; called by mutect2, pindel, varscan2
- TPH1 | c.669G>A p.E223= | Splice Region (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100000702; called by muse, mutect2
- TRABD2A | c.1145C>A p.P382H (on ENST00000409520 / NM_001277053.2; = p.P333H on NM_001080824.3) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.346); catalogued as COSV104378626, COSV52854944; called by muse, mutect2, varscan2
- TRIM29 | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100531541; called by muse, mutect2, varscan2
- TRIM4 | c.1450del p.W484Gfs*2 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs1254691563; ClinVar: not provided; called by mutect2, pindel
- TRIM67 | c.2323C>A p.L775M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as COSV100792057; called by muse, mutect2, varscan2
- TRPV2 | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.76); catalogued as COSV100641149; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL12 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs779062023, COSV99333244; called by muse, mutect2, varscan2
- TTN | c.14971C>T p.R4991* (on ENST00000591111; = p.R4064* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs886042995, COSV100599120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB2B | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV99455317; called by muse, mutect2
- UBAP2L | c.2096C>T p.T699M | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs746135849, COSV55172226; called by muse, mutect2, varscan2
- UBXN11 | c.926G>A p.G309D (on ENST00000374221 / NM_183008.2; = p.G276D on NM_145345.2) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99582069; called by muse, mutect2
- UMODL1 | c.3325G>A p.A1109T (on ENST00000408910 / NM_001004416.2; = p.A1237T on NM_173568.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as rs202150975; called by muse, mutect2, varscan2
- UNC13B | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); catalogued as COSV101036365; called by muse, mutect2, varscan2
- UNC79 | c.4609T>C p.Y1537H (on ENST00000393151 / NM_001346218.2; = p.Y1360H on NM_020818.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.66); catalogued as COSV56421220; called by muse, mutect2, varscan2
- UPF2 | c.3099A>T p.E1033D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1367060563, COSV62658267; called by muse, mutect2, varscan2
- UPRT | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV64912727; called by muse, mutect2
- USP9X | c.3503G>A p.R1168Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1271252455, COSV100198419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UTRN | c.402G>A p.W134* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100839684; called by muse, mutect2
- VCP | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734138; called by muse, mutect2, varscan2
- VPS37D | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as rs940224088, COSV100265257; called by muse, mutect2, varscan2
- VWA1 | c.462del p.M155Cfs*51 | Frame Shift Del (DEL) | VAF 39/166 reads (23%) | catalogued as rs760281341; called by mutect2, pindel, varscan2
- WDR5 | c.905-2A>G p.X302_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100681770; called by muse, mutect2, varscan2
- WNK3 | c.1559A>G p.Q520R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as COSV100670933; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as rs762052135; called by mutect2, varscan2
- YTHDC1 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs756535626, COSV60012804; called by muse, mutect2, varscan2
- ZBTB1 | c.1147del p.S383Vfs*6 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs747075448, COSV62437585; called by mutect2, varscan2
- ZBTB4 | c.1904A>C p.E635A | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV100262894; called by muse, mutect2, varscan2
- ZMYND8 | c.2963C>T p.T988I (on ENST00000311275 / NM_001363741.2; = p.T962I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99519821; called by muse, mutect2, varscan2
- ZNF266 | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100749352; called by muse, mutect2, varscan2
- ZNF277 | c.1094A>G p.K365R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV100702337; called by muse, mutect2, varscan2
- ZNF287 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV101209340; called by muse, mutect2, varscan2
- ZNF3 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs146443870; called by muse, mutect2, varscan2
- ZNF324 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as rs138669133; called by muse, mutect2, varscan2
- ZNF426 | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.828); catalogued as COSV99465020; called by muse, mutect2
- ZNF536 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200453890, COSV62825016; called by muse, mutect2, varscan2
- ZNF629 | c.2575C>T p.L859F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV99354615; called by muse, varscan2
- ZNF835 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV101606290; called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- ABCA5 | c.4752del p.F1584Lfs*27 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- ABCC4 | c.2648del p.L883Wfs*7 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- ACAP2 | c.470dup p.N157Kfs*22 | Frame Shift Ins (INS) | VAF 30/105 reads (29%) | called by mutect2, pindel, varscan2
- ADCY10 | c.341del p.N114Tfs*6 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- AP3B1 | c.674del p.N225Ifs*9 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- ARFGAP1 | c.883del p.S295Rfs*30 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- ARID1A | c.4800_4801del p.P1601* | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by pindel, varscan2
- ASPH | c.1597del p.D533Mfs*35 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.801_802del p.H267Qfs*9 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- BCL6 | c.957del p.N320Mfs*4 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- BRD3 | c.644del p.P215Qfs*28 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- C11orf58 | c.501dup p.D168Rfs*7 | Frame Shift Ins (INS) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- CCDC160 | c.976del p.*326del | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, varscan2
- CDHR1 | c.1721del p.P574Lfs*14 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, varscan2
- CDX1 | c.725del p.G242Afs*18 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- CERS2 | c.1073del p.G358Efs*8 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- CHD3 | c.4745del p.K1582Sfs*36 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- CILP | c.1539dup p.N514Efs*22 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- CKAP5 | c.1670dup p.K559Efs*22 | Frame Shift Ins (INS) | VAF 31/113 reads (27%) | called by mutect2, pindel, varscan2
- CPEB4 | c.2017del p.A673Pfs*42 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- CPSF3 | c.166_167del p.I56* | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by pindel, varscan2
- CSTF3 | c.1317del p.K439Nfs*33 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- DYNC1LI2 | c.927del p.F309Lfs*12 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- EFNB3 | c.991del p.Q331Rfs*39 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- FBXO8 | c.654del p.R219Vfs*17 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- GAB4 | c.153_174+7delinsGAGAAGAAGCTGAGGCTCTTTGTGAGTGC p.X51_splice | Splice Site (ONP) | VAF 14/59 reads (24%) | called by mutect2*, pindel, varscan2*
- GABRA4 | c.846_849del p.K282Nfs*11 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | called by mutect2, pindel, varscan2
- GCC2 | c.290del p.K97Rfs*4 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- GOLGA4 | c.6133del p.I2045Lfs*8 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- GRK5 | c.501del p.F167Lfs*15 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- HASPIN | c.1238_1239dup p.G414Lfs*14 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- HDAC5 | c.143dup p.G49Wfs*49 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- HECW2 | c.4175del p.G1392Vfs*19 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 35/59 reads (59%) | called by mutect2, varscan2
- JARID2 | c.416del p.P139Lfs*168 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.3125del p.G1042Efs*92 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel
- KIF1B | c.282dup p.A95Cfs*16 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- KMT2D | c.7548del p.N2517Ifs*26 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- KRT14 | c.143del p.G48Afs*70 | Frame Shift Del (DEL) | VAF 59/212 reads (28%) | called by mutect2, pindel, varscan2
- LAMA2 | c.442dup p.R148Pfs*12 | Frame Shift Ins (INS) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- LIPT1 | c.79del p.T27Qfs*2 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- MAPKAP1 | c.381dup p.S128Ifs*28 | Frame Shift Ins (INS) | VAF 24/92 reads (26%) | called by mutect2, varscan2
- MFAP1 | c.99del p.V34* | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- MIEF2 | c.540del p.P181Rfs*98 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- MROH6 | c.106dup p.Q36Pfs*18 | Frame Shift Ins (INS) | VAF 12/125 reads (10%) | called by mutect2, pindel
- MRPS14 | c.103_104del p.W35Afs*11 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by pindel, varscan2
- MYOCD | c.374del p.N125Tfs*9 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- NBN | c.1508dup p.N503Kfs*2 | Frame Shift Ins (INS) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- NCOA3 | c.3742C>A p.Q1248K (on ENST00000371998 / NM_181659.3; = p.Q1244K on NM_006534.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NCOA3 | c.3743A>T p.Q1248L (on ENST00000371998 / NM_181659.3; = p.Q1244L on NM_006534.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NDC80 | c.1315del p.I439Lfs*27 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- NF2 | c.683del p.K228Rfs*23 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- NFS1 | c.369dup p.T124Yfs*2 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- NOL8 | c.2738dup p.K914Efs*26 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, varscan2
- OBSL1 | c.5682G>T p.E1894D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by muse, mutect2
- OPA3 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by mutect2, varscan2
- OR13C4 | c.912del p.A305Lfs*3 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- OVOL2 | c.40del p.V14Sfs*23 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- PAK6 | c.627del p.T210Rfs*8 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- PCLO | c.4443dup p.D1482Rfs*2 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- PDE3A | c.511del p.E171Kfs*36 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PGAP2 | c.165+1del | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- POLR2A | c.1585del p.Q529Rfs*32 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- PRKCD | c.1300dup p.D434Gfs*13 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, varscan2
- PROX1 | c.1456del p.L486Ffs*3 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- PTEN | c.469dup p.E157Gfs*23 | Frame Shift Ins (INS) | VAF 35/113 reads (31%) | called by mutect2, pindel, varscan2
- PTPN3 | c.330del p.F110Lfs*21 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- RCVRN | c.345dup p.T116Dfs*6 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel
- SAMD3 | c.233del p.K78Rfs*42 | Frame Shift Del (DEL) | VAF 37/129 reads (29%) | called by mutect2, pindel, varscan2
- SESTD1 | c.340dup p.W114Lfs*6 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- SIRT1 | c.1557del p.E520Nfs*32 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- SLC14A1 | c.1067del p.N356Ifs*50 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by mutect2, pindel, varscan2
- SLC52A3 | c.162del p.L56Sfs*40 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, varscan2
- SLC5A3 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC9A1 | c.462del p.F155Sfs*36 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.810del p.M272Cfs*31 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.2314_2316dup p.N772dup | In Frame Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- SNTG1 | c.820dup p.I274Nfs*18 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, varscan2
- SPATA31A3 | c.2086del p.V696* | Frame Shift Del (DEL) | VAF 20/184 reads (11%) | called by mutect2, varscan2
- TGM7 | c.546del p.W182* | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- TIE1 | c.1801del p.Q601Rfs*7 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- TSC1 | c.608del p.L203Cfs*7 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.1557dup p.L520Afs*2 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | called by mutect2, varscan2
- UVSSA | c.1192del p.D398Mfs*186 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- VCL | c.1356del p.X452_splice | Splice Site (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- WDR4 | c.715del p.Q239Rfs*95 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- XRN1 | c.3310del p.C1104Vfs*7 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- ZC3H11A | c.1930del p.R644Gfs*8 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- ZNF526 | c.1681del p.R561Afs*41 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ZNF709 | c.936del p.K312Nfs*44 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- ABCB11 | c.3633C>T p.N1211= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs772714766, COSV55593882, COSV55602024; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- ADCYAP1R1 | c.745C>T p.L249= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV100416280; called by muse, mutect2, varscan2
- AEBP1 | c.2394C>T p.D798= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99788519; called by muse, mutect2, varscan2
- AGAP2 | c.3030G>A p.V1010= (on ENST00000547588 / NM_001122772.2; = p.V654= on NM_014770.4) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99222451; called by muse, mutect2, varscan2
- AKAP13 | c.1008T>C p.T336= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100773229; called by muse, mutect2, varscan2
- ALOX15 | c.9C>A p.L3= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99541233; called by muse, mutect2, varscan2
- ALPL | c.1446C>T p.H482= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs747980975, COSV66376562; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALS2 | c.2013C>T p.S671= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99968914; called by muse, mutect2, varscan2
- ANGPT4 | c.1263C>T p.S421= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1450748954, COSV101124659; called by muse, varscan2
- ANK3 | c.4839G>A p.G1613= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99778774; called by muse, mutect2
- AP3B2 | c.2355A>G p.E785= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99916154; called by muse, mutect2, varscan2
- APEH | c.813C>T p.G271= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99610587; called by muse, mutect2
- APOB | c.8784A>G p.S2928= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99264189; called by muse, mutect2, varscan2
- ARHGAP31 | c.1536C>T p.P512= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99956705; called by muse, mutect2, varscan2
- ARID4B | c.2835A>G p.S945= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs1386565507, COSV99935178; called by muse, mutect2, varscan2
- ARMC5 | c.2334G>A p.L778= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99192355; called by muse, mutect2, varscan2
- ASH1L | c.3277C>T p.L1093= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV64207785; called by muse, mutect2, varscan2
- ASIC5 | c.1305G>A p.A435= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs762133295, COSV73333074; called by muse, mutect2, varscan2
- ATP1A2 | c.660G>A p.S220= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs564452950, COSV100767678, COSV63404750; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- ATP2A2 | c.2019C>T p.R673= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100428455; called by muse, mutect2
- AXL | c.1074G>A p.A358= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs768522110, COSV99996107; called by muse, mutect2
- BBX | c.1290C>T p.C430= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100361152; called by muse, mutect2, varscan2
- BCAR1 | c.753G>A p.V251= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1405019776, COSV99366160; called by muse, mutect2, varscan2
- C15orf39 | c.2652G>A p.L884= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1307084741, COSV100641222; called by muse, mutect2, varscan2
- C19orf47 | c.1239G>A p.V413= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100775030; called by muse, mutect2, varscan2
- CAPN15 | c.900A>G p.E300= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs749841396, COSV99562251; called by muse, mutect2, varscan2
- CD247 | c.27G>A p.A9= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs757294201, COSV100758282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDAN1 | c.2775C>T p.H925= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs201778116, COSV62330722; called by muse, mutect2, varscan2
- CDC42BPB | c.3501T>C p.A1167= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100775277; called by muse, mutect2
- CDH1 | c.1644G>A p.L548= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99931433; called by muse, mutect2, varscan2
- CHAD | c.1023C>T p.D341= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs773421154, COSV99366082; called by muse, mutect2, varscan2
- CHD7 | c.8934T>C p.G2978= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1435780917, COSV101418057; called by muse, mutect2
- CHST10 | c.174C>T p.H58= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99958739; called by muse, mutect2, varscan2
- CHTF18 | c.1617C>T p.A539= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs111560773, COSV99135637; called by muse, mutect2, varscan2
- CIC | c.417G>A p.R139= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99359136; called by muse, mutect2, varscan2
- CKAP5 | c.6093C>T p.R2031= (on ENST00000529230 / NM_001008938.4; = p.R1971= on NM_014756.3) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100319389; called by muse, mutect2, varscan2
- CLCN6 | c.2052C>T p.S684= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs113714271, COSV100411658; called by muse, mutect2, varscan2
- CLCN7 | c.934T>C p.L312= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1469601701, COSV99246959; called by muse, mutect2, varscan2
- CLEC12B | c.672T>A p.S224= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100138919; called by muse, mutect2, varscan2
- CLEC18A | c.1260C>T p.N420= | Silent (SNP) | VAF 46/193 reads (24%) | catalogued as rs753891528, COSV55344919, COSV99846877; called by muse, mutect2, varscan2
- CNTNAP1 | c.1245C>T p.S415= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99226179; called by muse, mutect2, varscan2
- CRYBA2 | c.513C>T p.S171= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs761469307, COSV55386224; called by muse, mutect2, varscan2
- CTNND2 | c.1405T>C p.L469= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100473118; called by mutect2, varscan2
- DAAM1 | c.1728T>C p.P576= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100658102; called by muse, mutect2, varscan2
- DISP2 | c.3562C>A p.R1188= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99139766; called by muse, mutect2
- DISP3 | c.2601G>A p.V867= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1256516851, COSV99607670; called by muse, mutect2, varscan2
- DNAJC19 | c.273T>C p.P91= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100700136; called by muse, mutect2, varscan2
- DPP3 | c.2067C>T p.Y689= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV59149485; called by muse, mutect2, varscan2
- DRD5 | c.1230C>T p.Y410= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100431592; called by muse, mutect2, varscan2
- DUOX2 | c.1728T>C p.T576= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101199610; called by muse, mutect2, varscan2
- DVL2 | c.546C>A p.P182= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99138375; called by muse, mutect2, varscan2
- EIF2AK4 | c.4695A>G p.L1565= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV99139510; called by muse, mutect2, varscan2
- ELFN2 | c.882G>A p.S294= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs768267847, COSV101297489, COSV68745306; called by muse, mutect2, varscan2
- EPN2 | c.678C>A p.R226= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100127427; called by muse, mutect2, varscan2
- ERC1 | c.18C>T p.R6= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100705703; called by muse, mutect2, varscan2
- ERCC6 | c.813C>T p.F271= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs764319566, COSV63394280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXOC6B | c.480G>A p.L160= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1455932648, COSV99723157; called by muse, mutect2, varscan2
- EXOG | c.378C>A p.A126= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99815164; called by muse, mutect2
- FAT4 | c.9915C>T p.Y3305= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100627544, COSV58682190, COSV58683151; called by muse, mutect2, varscan2
- FGD3 | c.1425C>T p.S475= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs773672978, COSV100490442; called by muse, mutect2, varscan2
- FLT4 | c.2118G>A p.A706= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs148018153, COSV56115247; called by muse, mutect2, varscan2
- FLVCR2 | c.369T>C p.I123= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99471107; called by muse, mutect2, varscan2
- FNDC1 | c.1578C>T p.R526= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs530210486, COSV51945880; called by muse, varscan2
- FREM2 | c.1116C>T p.S372= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1339711862, COSV99747374; called by muse, mutect2, varscan2
- GABRA5 | c.1125C>T p.N375= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs780359473, COSV100164838; called by muse, mutect2, varscan2
- GDF7 | c.1119C>T p.Y373= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV55348523; called by muse, mutect2, varscan2
- GRSF1 | c.831C>T p.D277= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs757537493, COSV99635552; called by muse, mutect2, varscan2
- H1-5 | c.213C>T p.A71= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs749604290, COSV100137744; called by muse, mutect2, varscan2
- HEATR1 | c.4683T>C p.V1561= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100857507; called by muse, mutect2
- HRH2 | c.213G>A p.V71= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99199546; called by muse, mutect2, varscan2
- HUNK | c.1644C>A p.P548= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99528132; called by muse, mutect2, varscan2
- HYDIN | c.12223C>T p.L4075= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV101124951; called by mutect2, varscan2
- IFFO1 | c.603C>T p.H201= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100350889; called by muse, mutect2, varscan2
- ITGB6 | c.378C>T p.R126= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99324235; called by muse, mutect2, varscan2
- KIF18B | c.126T>C p.P42= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs766773099, COSV100191877; called by muse, mutect2, varscan2
- KIRREL3 | c.1599G>A p.P533= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs565358488, COSV101375180; called by muse, mutect2, varscan2
- KMT2D | c.3606C>T p.S1202= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs369602516; ClinVar: benign; called by muse, mutect2, varscan2
- LAMA5 | c.2268C>T p.D756= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99438527; called by muse, mutect2, varscan2
- LAMB1 | c.90C>T p.C30= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV55969026; called by muse, mutect2, varscan2
- LAMC3 | c.3969A>G p.S1323= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs937513555, COSV100735910; called by muse, mutect2, varscan2
- LGR6 | c.2364C>T p.P788= (on ENST00000367278 / NM_001017403.1; = p.P736= on NM_021636.3) | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs370607325; called by muse, mutect2, varscan2
- LILRB2 | c.1740C>A p.S580= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV100079097; called by muse, mutect2, varscan2
- LONP1 | c.2049C>T p.G683= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100638549; called by muse, mutect2, varscan2
- LRCH4 | c.1692G>T p.L564= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99776155; called by muse, mutect2, varscan2
- LRP2 | c.4299T>C p.S1433= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99786948; called by muse, mutect2
- LRRC37A3 | c.585G>A p.L195= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100140902; called by muse, mutect2, varscan2
- LRRC8A | c.1152G>A p.P384= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs980321768, COSV99396312; called by muse, mutect2, varscan2
- LRRN4 | c.1077C>T p.P359= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV101125379; called by muse, mutect2, varscan2
- LRRTM2 | c.477G>A p.L159= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99217687; called by muse, mutect2, varscan2
- MAP7D2 | c.1002G>A p.A334= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs144221752, COSV101107217; called by muse, mutect2, varscan2
- MAPT | c.2457G>A p.T819= (on ENST00000262410 / NM_001377265.1; = p.T427= on NM_005910.5) | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs369954009; ClinVar: likely benign; called by muse, mutect2, varscan2
- MCFD2 | c.216G>A p.L72= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100109031; called by muse, mutect2, varscan2
- MEPCE | c.1092A>G p.K364= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99439837; called by muse, mutect2, varscan2
- MIB1 | c.237G>A p.K79= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV55092726, COSV55093454; called by muse, mutect2
- MSGN1 | c.525C>T p.I175= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV55263484; called by mutect2, varscan2
- MTMR3 | c.2199G>A p.E733= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100070531; called by muse, mutect2
- MYO18B | c.1584G>A p.T528= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs572078069, COSV100122854; called by muse, mutect2, varscan2
- NAA11 | c.330C>T p.H110= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs774663471, COSV54514307; called by muse, mutect2, varscan2
- NDUFA10 | c.933T>C p.P311= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99401255; called by muse, mutect2, varscan2
- NKAPD1 | c.759G>A p.K253= (on ENST00000280352 / NM_001082970.2; = p.K254= on NM_018195.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99735953; called by muse, mutect2
- NPHS1 | c.2007C>T p.S669= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100799649, COSV62289269; called by muse, mutect2, varscan2
- NR0B1 | c.741G>A p.A247= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100973422; called by muse, mutect2, varscan2
- NRDC | c.2715C>T p.D905= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs781711587, COSV61401970; called by muse, mutect2, varscan2
- NUP205 | c.4602T>C p.R1534= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99606594; called by muse, mutect2, varscan2
- OCA2 | c.2229G>A p.P743= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs41307118, COSV62360004; called by muse, mutect2
- OPTC | c.651C>T p.P217= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs775952554, COSV65868466; called by muse, mutect2, varscan2
- OR10Q1 | c.634C>T p.L212= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV57471389; called by mutect2, varscan2
- OR4C15 | c.483T>C p.A161= (on ENST00000314644; = p.A107= on NM_001001920.2) | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100115452; called by muse, mutect2
- OR6B3 | c.516C>T p.N172= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs768029131, COSV60117071; called by muse, mutect2, varscan2
- OSBPL1A | c.558G>A p.R186= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1424249269, COSV100111273; called by muse, mutect2, varscan2
- P2RY2 | c.729C>T p.S243= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100232653; called by muse, mutect2, varscan2
- PAGR1 | c.309G>A p.Q103= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100232620; called by muse, mutect2
- PCDHGA12 | c.2034C>T p.L678= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV99338640; called by muse, mutect2, varscan2
- PGM1 | c.741G>A p.S247= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs142222746; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PPP1R26 | c.1341C>A p.P447= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs760968240, COSV100778010; called by muse, mutect2, varscan2
- PRKCH | c.1005C>T p.S335= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs754418354, COSV100272934; called by muse, mutect2, varscan2
- PTPRD | c.5061C>T p.C1687= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100643806; called by mutect2, varscan2
- PTPRN2 | c.2061G>A p.T687= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs781385233, COSV101233887; called by muse, mutect2
- PWWP2A | c.699T>C p.C233= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100193735; called by muse, mutect2, varscan2
- RBM42 | c.1089G>A p.A363= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs371648571; called by muse, mutect2, varscan2
- RGMB | c.1272C>T p.V424= (on ENST00000513185 / NM_001366508.1; = p.V465= on NM_001012761.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as rs1249108571, COSV100374763; called by muse, mutect2, varscan2
- RIPK3 | c.657A>G p.E219= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99353013, COSV99353015; called by muse, mutect2
- RP1 | c.5025T>G p.S1675= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99606578; called by muse, mutect2, varscan2
- RRP9 | c.468C>A p.P156= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV51753766, COSV99232230; called by muse, mutect2, varscan2
- SAP130 | c.522T>C p.V174= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99384243; called by muse, mutect2, varscan2
- SEMA4D | c.2163C>T p.H721= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs1483448475, COSV100358043; called by muse, mutect2, varscan2
- SH3D21 | c.1545C>A p.V515= (on ENST00000453908 / NM_001162530.2; = p.V404= on NM_024676.5) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99583944; called by muse, mutect2
- SHKBP1 | c.1467C>T p.G489= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV52538090; called by muse, mutect2, varscan2
- SLC6A11 | c.216C>T p.N72= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs756244162, COSV99594171; called by muse, mutect2, varscan2
- SLC6A19 | c.816C>T p.G272= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs370546018; called by muse, mutect2, varscan2
- SMCHD1 | c.5937G>A p.T1979= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs776794549, COSV100303113, COSV57969312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTAN1 | c.3819C>T p.R1273= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100823316; called by muse, mutect2, varscan2
- SRD5A2 | c.216C>T p.P72= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV99252274; called by muse, mutect2, varscan2
- STAB1 | c.2232C>T p.G744= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100401348; called by muse, mutect2, varscan2
- STK11IP | c.2142C>T p.H714= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs925123018, COSV99822416; called by muse, mutect2, varscan2
- TAF1A | c.483G>A p.E161= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100600931, COSV61918853; called by muse, mutect2, varscan2
- TAS1R1 | c.1662G>A p.P554= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs776544185, COSV59840748; called by muse, mutect2, varscan2
- TCOF1 | c.3612A>G p.S1204= (on ENST00000377797 / NM_001135243.1; = p.S1127= on NM_000356.4) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as CS094493, COSV100076990; called by muse, mutect2, varscan2
- TG | c.3012C>T p.F1004= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99599532, COSV99603739; called by muse, mutect2, varscan2
- TRANK1 | c.3048G>A p.A1016= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs772915260, COSV57159420; called by muse, varscan2
- TRIP10 | c.522G>A p.Q174= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs762979062, COSV57573159; called by muse, mutect2, varscan2
- TRMT12 | c.165C>T p.G55= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TUBB | c.882C>T p.F294= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs1353532618, COSV100013291; called by muse, mutect2, varscan2
- UACA | c.2625G>A p.T875= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs370496255; called by muse, mutect2, varscan2
- UGT2B10 | c.174A>G p.S58= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV99607970; called by muse, mutect2, varscan2
- USHBP1 | c.1165C>T p.L389= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99394060; called by muse, mutect2, varscan2
- USP34 | c.4878A>G p.S1626= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101276771; called by muse, mutect2, varscan2
- ZC3H11A | c.2397C>T p.D799= | Silent (SNP) | VAF 17/171 reads (10%) | catalogued as COSV100142176; called by muse, mutect2, varscan2
- ZNF384 | c.258G>A p.Q86= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100158246, COSV60530379; called by muse, mutect2, varscan2
- ZNF816 | c.1038T>C p.C346= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99554482; called by muse, mutect2, varscan2
- ZSWIM1 | c.39G>A p.L13= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99666224; called by muse, mutect2, varscan2
- ZZZ3 | c.1881T>C p.G627= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100890223; called by muse, mutect2, varscan2
- AC024940.1 | n.2302G>A | RNA (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- AL136982.4 | n.478C>T | RNA (SNP) | VAF 94/324 reads (29%) | catalogued as rs565840080; called by muse, mutect2, varscan2
- CARMIL1 | c.614+1527C>T | Intron (SNP) | VAF 3/23 reads (13%) | catalogued as rs1425668229; called by muse, mutect2
- CEP295 | c.5851-193del | Intron (DEL) | VAF 27/85 reads (32%) | catalogued as rs754124024; called by mutect2, pindel, varscan2
- DMKN | c.1239+238C>T | Intron (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100303302; called by muse, mutect2, varscan2
- HLA-F | chr6:29726999 C>T | 3'Flank (SNP) | VAF 22/83 reads (27%) | catalogued as rs752469158, COSV52576073, COSV99465748; called by muse, mutect2, varscan2
- KAT5 | c.13-13G>A | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100383841; called by muse, mutect2, varscan2
- KIAA0586 | c.-4dup | 5'UTR (INS) | VAF 10/59 reads (17%) | catalogued as rs768591621; called by mutect2, pindel, varscan2
- MASP1 | c.1303+5686C>T | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as rs745444812, COSV56221819, COSV99962704; called by muse, mutect2, varscan2
- PFKL | c.*2G>A | 3'UTR (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100297099; called by muse, mutect2, varscan2
- SORBS2 | c.685-7526T>A | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99509840; called by muse, varscan2
- STAG3L3 | n.454G>A | RNA (SNP) | VAF 10/67 reads (15%) | called by mutect2, varscan2
